MMRF case MMRF_1525 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7563241e-9cce-47ba-99c3-97c27eafce4c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,111 days); ISS stage: I; Days to last known disease status: 1,225 days (3.4 years); Days to last follow up: 1,225 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 27 days; Days to treatment end: 208 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 208 days; Days to treatment end: 273 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 889 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -99 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 340 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 36.6 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 3.31 µg/mL; Lactate Dehydrogenase 6.02 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 9.5 g/dL; Glucose 5.56 mmol/L; C-Reactive Protein 1.48 mg/dL.
- Day 1 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 388 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 38.2 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 3.31 µg/mL; Lactate Dehydrogenase 6.02 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 9.4 g/dL; Glucose 6.27 mmol/L.
- Day 76 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 34.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.13 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.99 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 7.12 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 167 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 2.1 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 7.02 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.
- Day 251: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.61 mmol/L.
- Day 343: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.6 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 5.01 mmol/L.
- Day 426: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.91 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 2.56 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.68 mmol/L.
- Day 539 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.92 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 2.58 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 609 (ECOG 0): M Protein 0.1 g/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 2.58 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.57 mmol/L.
- Day 727: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.66 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 2.59 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.55 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.06 mmol/L.
- Day 881: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.53 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.57 mmol/L.
- Day 979: Serum Free Immunoglobulin Light Chain, Kappa 18.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 1,099: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Hemoglobin 8.25 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.55 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 5.06 mmol/L.
- Day 1,162: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.65 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.34 mmol/L.
- Day 1,225: M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Hemoglobin 7.94 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.63 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -99: Weight: 79 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Leukemia.

Biospecimens (2 samples)
- Sample MMRF_1525_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -99 days.
- Sample MMRF_1525_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -99 days.
